Gene-level copy-number profile of tumor specimen TCGA-FA-A82F-01A from TCGA case TCGA-FA-A82F, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Small intestine, NOS; Age at diagnosis: 48.8 years (17,819 days).
Specimen TCGA-FA-A82F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.9755c987-1430-4961-b0c9-2fdb58d778ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FA-A82F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5c1c5b86-b722-4a77-a4f5-f4cc3c49d025

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 616; copy number 3: 5,862; copy number 4: 29,856; copy number 5: 16,877; copy number 6: 4,322; copy number 7: 1,447; copy number 8: 4; copy number 9: 188; copy number 10: 212; copy number 11: 14; copy number 13: 94; copy number 14: 104; copy number 15: 6; copy number 22: 79; copy number 24: 136.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FA-A82F-01A-11D-A381-01): tumor purity 0.43, ploidy 4.52, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 833 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,450,520–63,197,037, 73 genes, copy number 9–14 (within-gene range 5–14) (broad region; genes not listed).
- chr2:63,168,600–63,233,577, 2 genes, copy number 9: Metazoa_SRP, MTFR2P1.
- chr4:169,912,705–170,605,450, 13 genes, copy number 9: AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512, AC074255.1, HSP90AA6P.
- chr5:38,399,814–39,274,528, 17 genes, copy number 22 (within-gene range 8–22): EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1.
- chr5:39,718,984–40,755,963, 13 genes, copy number 11 (within-gene range 4–11): INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4.
- chr7:70,972–4,883,716, 99 genes, copy number 9 (broad region; genes not listed).
- chr14:100,323,339–101,335,497, 136 genes, copy number 24 (broad region; genes not listed).
- chr16:23,962,951–23,963,351, 1 gene, copy number 11: AC130454.1.
- chr19:27,638,483–30,085,893, 62 genes, copy number 9 (broad region; genes not listed).
- chr19:30,665,274–37,304,395, 255 genes, copy number 10–14 (within-gene range 3–14) (broad region; genes not listed).
- chr19:45,710,629–45,730,896, 1 gene, copy number 22 (within-gene range 3–22): FBXO46.
- chr19:45,733,439–45,902,613, 13 genes, copy number 22: BHMG1, SIX5, AC074212.1, DM1-AS, DMPK, AC011530.1, DMWD, RSPH6A, SYMPK, AC092301.1, FOXA3, IRF2BP1, MYPOP.
- chr19:46,101,122–47,210,636, 54 genes, copy number 15–22 (within-gene range 3–22): AC007785.1, AC007785.2, IGFL3, TGIF1P1, IGFL2, AC006262.2, IGFL2-AS1, IGFL1P1, AC006262.1, RPL12P41, AC006262.3, IGFL1, AC006262.4, IGFL1P2, HIF3A, RNU6-924P, AC007193.2, PPP5C, AC007193.1, AC007193.3, CCDC8, PNMA8C, PNMA8A, PPP5D1, PNMA8B, AC011484.1, AC011551.1, GAPDHP38, CALM3, AC093503.1, PTGIR, GNG8, AC093503.2, DACT3, DACT3-AS1, PRKD2, RN7SL364P, MIR320E, STRN4, AC008635.1, Y_RNA, FKRP, SLC1A5, AC008622.2, AC008622.3, HNRNPMP2, AC008622.1, AP2S1, ARHGAP35, AC008895.1, NPAS1, TMEM160, ZC3H4, SAE1.
- chr19:55,226,638–56,538,575, 94 genes, copy number 13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
